Somatic mutation profile of tumor specimen TCGA-D7-6527-01A (aliquot TCGA-D7-6527-01A-11D-1800-08) from TCGA case TCGA-D7-6527, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.4 years (22,793 days).
Specimen TCGA-D7-6527-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8055ae80-79da-47e2-8f7b-ba5fe78f8e37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6527-10A (Blood Derived Normal), aliquot TCGA-D7-6527-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46494d4f-2687-42e9-a671-a21ea80966ee

The open-access MAF lists 226 somatic variants for this specimen: 175 protein-altering or splice-affecting, 46 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 46, Nonsense Mutation 10, Frame Shift Del 5, Splice Site 3, RNA 3, In Frame Del 2, Splice Region 2, 3'UTR 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as rs137853218, CM081410, COSV57192495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10882A>C p.S3628R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV71291361; called by muse, mutect2, varscan2
- ACE2 | c.1373A>C p.K458T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV53026127; called by muse, mutect2, varscan2
- ADAMTS3 | c.1063T>G p.F355V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54396568; called by muse, mutect2, varscan2
- ADAMTS5 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs768917351, COSV53181660; called by muse, mutect2, varscan2
- AKAP6 | c.6913A>C p.N2305H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); catalogued as COSV55222302; called by muse, mutect2
- ANK2 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as COSV52174296; called by muse, mutect2, varscan2
- ANKRD30A | c.2663A>C p.K888T (on ENST00000611781; = p.K832T on NM_052997.2) | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV64615402; called by muse, mutect2
- ANKRD30A | c.2930T>G p.L977R (on ENST00000611781; = p.L921R on NM_052997.2) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV64615413; called by muse, mutect2, varscan2
- APOB | c.8170C>A p.P2724T | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51943849; called by muse, mutect2, varscan2
- AR | c.877T>C p.S293P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.998); catalogued as COSV65960269, COSV65964282; called by muse, mutect2, varscan2
- ARHGAP33 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as rs1395913915, COSV50134862; called by muse, mutect2, varscan2
- ARHGEF11 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as rs1326426735, COSV59356235; called by muse, mutect2, varscan2
- ARL13A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs553228239, COSV65880071; called by muse, mutect2, varscan2
- AUTS2 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61417035; called by muse, mutect2, varscan2
- BBS7 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.537); catalogued as COSV52657991; called by muse, mutect2
- BNIP1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776652848, COSV51571239; called by muse, mutect2, varscan2
- CACNA2D1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.403); catalogued as COSV62385434; called by muse, mutect2, varscan2
- CACNA2D3 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as rs1417940298, COSV55537866; called by muse, mutect2, varscan2
- CCDC107 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs756761846, COSV58397557; called by muse, mutect2, varscan2
- CCDC172 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs769284084, COSV60938984; called by muse, mutect2, varscan2
- CCNA2 | c.1132C>G p.R378G | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV54666909, COSV99697188; called by muse, mutect2, varscan2
- CD1D | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63809472; called by muse, mutect2, varscan2
- CD5L | c.564A>C p.Q188H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63822560; called by muse, mutect2, varscan2
- CDH11 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV51753026, COSV51757269, COSV99220171; called by muse, mutect2, varscan2
- CFHR4 | c.1611T>G p.Y537* (on ENST00000367416 / NM_001201551.2; = p.Y291* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as rs1217545171, COSV52232268; called by muse, mutect2, varscan2
- CHCHD2 | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as rs200052223, COSV68170074; called by muse, mutect2, varscan2
- CHL1 | c.1910A>C p.D637A (on ENST00000397491 / NM_001253387.1; = p.D653A on NM_006614.4) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV56598340; called by muse, mutect2
- CHRM2 | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.854); catalogued as rs779600445, COSV57778382; called by muse, mutect2
- CHRNA6 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52379613, COSV52380356; called by muse, mutect2, varscan2
- CNTN6 | c.220A>C p.S74R | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV63160327, COSV63180477; called by muse, varscan2
- COL12A1 | c.3440T>G p.L1147R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59401029; called by muse, mutect2, varscan2
- CR1 | c.5562C>G p.I1854M | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs772261193, COSV65460311; called by muse, mutect2, varscan2
- CSMD1 | c.10231T>G p.L3411V (on ENST00000520002; = p.L3410V on NM_033225.6) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100155482, COSV59336928; called by muse, mutect2, varscan2
- CUBN | c.2556A>C p.Q852H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.878); catalogued as COSV64710110, COSV64721355, COSV64726238; called by muse, mutect2, varscan2
- CYP4F3 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs376964564; called by muse, mutect2, varscan2
- DCC | c.3817C>A p.P1273T | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as COSV71435874; called by muse, mutect2, varscan2
- DCDC1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV60849991; called by muse, mutect2, varscan2
- DCHS1 | c.7181C>T p.A2394V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.145); catalogued as rs1200370785, COSV55038968; called by muse, mutect2, varscan2
- DEFB118 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as rs761656795, COSV53620921; called by muse, mutect2, varscan2
- DGLUCY | c.1026T>G p.H342Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56368050; called by muse, mutect2, varscan2
- DNAH7 | c.3936-1G>C p.X1312_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV56774595; called by muse, mutect2
- EDNRB | c.1503del p.K501Nfs*11 (on ENST00000377211 / NM_001201397.1; = p.K411Nfs*11 on NM_000115.5) | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV57520292; called by mutect2, pindel, varscan2
- EGFLAM | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.253); catalogued as COSV59309929; called by muse, mutect2, varscan2
- EIF3A | c.3859C>T p.R1287* | Nonsense Mutation (SNP) | VAF 69/199 reads (35%) | catalogued as COSV64962123; called by muse, mutect2, varscan2
- EPHA3 | c.1874A>C p.K625T | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1365375680, COSV60715642; called by muse, mutect2, varscan2
- EPHA6 | c.2170A>G p.R724G (on ENST00000389672 / NM_001080448.3; = p.R116G on NM_173655.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV67582308; called by muse, mutect2, varscan2
- ETV1 | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54146683; called by muse, mutect2, varscan2
- F13B | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs762576464, COSV66374805; called by muse, mutect2, varscan2
- F9 | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54381468; called by muse, mutect2, varscan2
- FAM193A | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV61196447; called by muse, mutect2, varscan2
- FMN2 | c.4865T>G p.I1622S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV60414894; called by muse, mutect2, varscan2
- FMR1NB | c.520T>G p.F174V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63272860; called by muse, mutect2, varscan2
- FSCB | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.732); catalogued as rs147180788, COSV100468718; called by muse, mutect2, varscan2
- FSTL5 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60183600, COSV60210915; called by muse, mutect2, varscan2
- GLIPR1L2 | c.406A>C p.S136R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57554952; called by muse, mutect2, varscan2
- GSTA1 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs530255410, COSV58016144; called by muse, mutect2, varscan2
- H2BC13 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62440987; called by muse, mutect2, varscan2
- HECW2 | c.4134A>C p.E1378D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV53666482; called by muse, mutect2, varscan2
- HSPD1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs1185021844, COSV61445235; called by muse, mutect2, varscan2
- HTR7 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53285483, COSV53286176; called by muse, mutect2, varscan2
- IFNA17 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV69738155, COSV69738225; called by muse, mutect2, varscan2
- IGF1R | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51318840; called by muse, mutect2, varscan2
- IVL | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV64216195; called by muse, mutect2, varscan2
- KASH5 | c.1338A>C p.R446S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.086); catalogued as COSV71358178; called by muse, mutect2, varscan2
- KCNJ12 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100054005; called by muse, mutect2, varscan2
- KCNQ3 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464164, COSV66476011; called by muse, mutect2, varscan2
- KCNQ5 | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59671208; called by muse, mutect2, varscan2
- KCNT2 | c.2735T>G p.L912R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54068593; called by muse, mutect2
- KDM8 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201781237, COSV53730733; called by muse, mutect2, varscan2
- KIAA1109 | c.4164G>A p.M1388I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV52682761; called by muse, mutect2, varscan2
- KIR3DL2 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99551744; called by muse, mutect2, varscan2
- KLHL4 | c.1988T>G p.V663G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64145027, COSV64145339; called by muse, mutect2, varscan2
- KLRC2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs375539764, COSV101122642; called by muse, mutect2, varscan2
- KRTAP4-5 | c.90C>A p.C30* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV58352838; called by muse, mutect2, varscan2
- LACC1 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57829465; called by muse, mutect2, varscan2
- LAMA3 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs750852201, COSV58073439; called by muse, mutect2, varscan2
- LCE2B | c.175A>G p.S59G | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1295572017, COSV64227842; called by muse, mutect2, varscan2
- LRRC52 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 59/261 reads (23%) | catalogued as COSV54232908; called by muse, mutect2, varscan2
- MACF1 | c.18562G>C p.D6188H (on ENST00000372915; = p.D4233H on NM_012090.5) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV57132083; called by muse, mutect2, varscan2
- MAGEA4 | c.747A>C p.Q249H | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV52342379; called by muse, mutect2, varscan2
- MCM2 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs779228557, COSV54035176; called by muse, mutect2, varscan2
- MGAT4A | c.1444T>G p.L482V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV53848717; called by muse, mutect2
- MPP5 | c.1851G>A p.K617= | Splice Region (SNP) | VAF 21/80 reads (26%) | catalogued as rs753897094, COSV55530934; called by muse, mutect2, varscan2
- MROH9 | c.1437A>C p.E479D | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV63012389; called by muse, mutect2
- MRPS30 | c.896T>G p.F299C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50181805; called by muse, mutect2, varscan2
- MUC15 | c.883A>G p.S295G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV55555855; called by muse, mutect2, varscan2
- MYO7B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV67344334, COSV67346872; called by muse, mutect2, varscan2
- NAALADL2 | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101435742, COSV70795118; called by muse, mutect2
- NCOA5 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.434); catalogued as COSV51645771; called by muse, mutect2, varscan2
- NEXMIF | c.2776A>C p.N926H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV50055938; called by muse, mutect2, varscan2
- NFATC4 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs955445198, COSV51596369; called by muse, mutect2, varscan2
- NR1D2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56992808; called by muse, mutect2, varscan2
- NXT2 | c.302A>C p.K101T (on ENST00000372106 / NM_001242617.2; = p.K156T on NM_018698.5) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV54297010; called by muse, mutect2, varscan2
- OLR1 | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV58872083; called by muse, mutect2, varscan2
- OR10Z1 | c.134T>G p.I45S | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63525658; called by muse, mutect2, varscan2
- OR2AK2 | c.393T>G p.H131Q | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV63557040; called by muse, varscan2
- OR2M7 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58738919; called by muse, mutect2
- OR2T3 | c.486G>T p.L162F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1458299394, COSV100613065; called by muse, mutect2
- OR2T4 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV63544554, COSV63544706; called by muse, mutect2, varscan2
- OR4K5 | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60004280; called by muse, mutect2, varscan2
- OR4M1 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60062563; called by muse, mutect2
- OR5D16 | c.631A>C p.S211R | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65722427; called by muse, mutect2, varscan2
- OR5F1 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs776392369, COSV53546632, COSV53546830; called by muse, mutect2, varscan2
- OR5L2 | c.32A>C p.E11A | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV65723460, COSV65724594, COSV65724996; called by muse, mutect2, varscan2
- OR5M10 | c.4T>G p.L2V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV73242380; called by muse, mutect2, varscan2
- OR6B1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs374206359, COSV68769859; called by muse, mutect2, varscan2
- OTOA | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs145435704; called by muse, mutect2, varscan2
- PAPPA | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772431336, COSV60287655; called by muse, mutect2, varscan2
- PAPPA2 | c.2987T>G p.L996R | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62804129; called by muse, mutect2, varscan2
- PAPPA2 | c.3837T>A p.F1279L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62790719; called by muse, mutect2
- PCLO | c.12606A>C p.K4202N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61629441; called by muse, mutect2, varscan2
- PLCL1 | c.1674A>C p.E558D | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as COSV70849967; called by muse, mutect2
- PPP1R3A | c.2284A>C p.S762R | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV52887252; called by muse, mutect2, varscan2
- PREX2 | c.3767-2A>T p.X1256_splice | Splice Site (SNP) | VAF 26/95 reads (27%) | catalogued as COSV55785275; called by muse, mutect2, varscan2
- PREX2 | c.4233A>T p.A1411= | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV55785286; called by muse, mutect2
- PSEN2 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV60917278; called by muse, mutect2, varscan2
- PTPN13 | c.4085A>C p.K1362T (on ENST00000411767 / NM_080683.3; = p.K1343T on NM_006264.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV57411977; called by muse, mutect2
- RHEB | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51263506; called by muse, mutect2, varscan2
- RIF1 | c.7357A>G p.N2453D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV54620308; called by muse, mutect2, varscan2
- RPL10L | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53559335, COSV53559592; called by muse, mutect2, varscan2
- RUBCNL | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV59791035; called by muse, mutect2, varscan2
- RYR3 | c.7436C>T p.S2479F (on ENST00000389232; = p.S2480F on NM_001036.6) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66800386; called by muse, mutect2, varscan2
- SDK1 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 161/301 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs200916324, COSV67379142; called by muse, mutect2, varscan2
- SLCO5A1 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52663472; called by muse, mutect2, varscan2
- SLIT2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs772070012, COSV56582894; called by muse, mutect2, varscan2
- SLIT2 | c.1249T>G p.S417A | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56582906; called by muse, mutect2, varscan2
- SLITRK2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59427160, COSV59427299; called by muse, mutect2, varscan2
- SPDYE5 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 64/1638 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV71596406; called by muse, mutect2
- SPOCK1 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56456250, COSV56457360; called by muse, mutect2, varscan2
- SPTA1 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.222); catalogued as COSV100935317, COSV63756608; called by muse, mutect2, varscan2
- TDRD6 | c.3753T>G p.F1251L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV60176980; called by muse, mutect2, varscan2
- TECPR2 | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763118922, COSV63970143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFAP2D | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV50411650, COSV50433932; called by muse, mutect2, varscan2
- TLR4 | c.1316A>C p.E439A (on ENST00000355622 / NM_138554.5; = p.E399A on NM_003266.4) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62922373, COSV62923773, COSV62924192; called by muse, mutect2, varscan2
- TMF1 | c.2821G>A p.V941I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV68375038; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 103/207 reads (50%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TPTE | c.239A>G p.K80R (on ENST00000618007 / NM_199261.4; = p.K62R on NM_199259.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.227); catalogued as rs757230899; called by muse, mutect2, varscan2
- TRAT1 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.202); catalogued as COSV55469671, COSV55470668; called by muse, mutect2, varscan2
- TRHDE | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53854439; called by muse, mutect2
- TTC6 | c.1340C>G p.P447R (on ENST00000267368; = p.P1813R on NM_001310135.3) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57451821; called by muse, mutect2, varscan2
- TTN | c.82724A>C p.N27575T (on ENST00000591111; = p.N20151T on NM_003319.4) | Missense Mutation (SNP) | VAF 52/1562 reads (3%) | PolyPhen probably damaging (0.995); catalogued as COSV60190091; called by muse, mutect2
- TTN | c.79447G>A p.E26483K (on ENST00000591111; = p.E19059K on NM_003319.4) | Missense Mutation (SNP) | VAF 152/187 reads (81%) | PolyPhen probably damaging (0.994); catalogued as rs1295072546, COSV60190131; called by muse, mutect2, varscan2
- TTN | c.21396A>C p.Q7132H (on ENST00000591111; = p.Q6205H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/195 reads (15%) | PolyPhen benign (0); catalogued as COSV60190155; called by muse, mutect2, varscan2
- TUBA3C | c.1218C>G p.H406Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV68029105; called by muse, mutect2
- TUBGCP6 | c.3241G>A p.G1081R | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs752428490, COSV50541857; called by muse, mutect2, varscan2
- UBE2E3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 37/145 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV66585652; called by muse, mutect2, varscan2
- USH2A | c.14206G>A p.E4736K | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs12085358, COSV56399952; called by muse, mutect2, varscan2
- USH2A | c.5097A>C p.Q1699H | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV56399964; called by muse, mutect2, varscan2
- USP9X | c.5822G>A p.R1941H | Missense Mutation (SNP) | VAF 97/114 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374231846, COSV61071988; called by muse, mutect2, varscan2
- WDR6 | c.3109G>T p.E1037* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as COSV58246165; called by muse, varscan2
- ZEB2 | c.2584T>G p.L862V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57953512, COSV57953777; called by muse, mutect2, varscan2
- ZFP14 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV54202943, COSV54203559; called by muse, mutect2, varscan2
- ZNF33B | c.1937T>C p.F646S | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63942947; called by muse, mutect2
- ZNF416 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52185116; called by muse, mutect2, varscan2
- ZNF492 | c.946A>G p.K316E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71762172; called by muse, mutect2, varscan2
- ZNF536 | c.3749A>T p.K1250M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62828801; called by muse, mutect2, varscan2
- ZNF571 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV60734088; called by muse, mutect2, varscan2
- ZNF804A | c.2487A>C p.K829N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV56458852; called by muse, mutect2, varscan2
- ZNF804B | c.2653A>G p.K885E | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV60839763; called by muse, mutect2, varscan2
- AHCYL1 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, varscan2
- C6orf58 | c.382_384del p.W128del | In Frame Del (DEL) | VAF 24/164 reads (15%) | called by pindel, varscan2
- CTDSPL2 | c.1261del p.E421Kfs*13 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- DLGAP1 | c.690_702del p.S231Tfs*14 | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | called by mutect2, pindel, varscan2
- ICOS | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2
- IGSF11 | c.883_885del p.S295del (on ENST00000393775 / NM_001015887.3; = p.S294del on NM_152538.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 16/68 reads (24%) | called by pindel, varscan2
- KRTAP21-2 | c.177T>G p.Y59* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2
- LRRC23 | c.487_490+7del p.X163_splice | Splice Site (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel
- MEI1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- NBPF11 | c.2458C>T p.L820F | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NRXN3 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.116); called by muse, varscan2
- OR8G2P | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHA8 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.172del p.Y58Tfs*33 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- ZNF99 | c.2243T>G p.L748R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.1096A>C p.R366= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV101002045, COSV65397061, COSV65406871; called by muse, mutect2, varscan2
- APP | c.2127T>C p.G709= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV61001246; called by muse, mutect2, varscan2
- ASXL3 | c.3126T>C p.S1042= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV52472534; called by muse, mutect2, varscan2
- CDH10 | c.1488T>C p.F496= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV52588486, COSV52592006; called by muse, mutect2, varscan2
- CNTN6 | c.1923G>A p.V641= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV63180483; called by muse, mutect2, varscan2
- CPED1 | c.2109T>G p.S703= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV60004759; called by muse, mutect2, varscan2
- DIAPH2 | c.327C>A p.L109= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV61281084; called by muse, mutect2, varscan2
- EAF2 | c.507A>C p.L169= | Silent (SNP) | VAF 37/225 reads (16%) | catalogued as COSV56545162; called by muse, mutect2, varscan2
- EXOG | c.306G>A p.K102= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV55064059; called by muse, mutect2, varscan2
- FCN2 | c.642C>T p.D214= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs142072878; called by muse, mutect2, varscan2
- GPR158 | c.1035C>T p.F345= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs767413538, COSV100894148, COSV66270021; called by muse, mutect2, varscan2
- GRIA3 | c.180C>T p.T60= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV52071182, COSV99988509; called by muse, mutect2
- GUCY1A1 | c.936A>G p.R312= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56653658; called by muse, mutect2, varscan2
- HMCN1 | c.10656T>G p.A3552= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV54918469; called by muse, mutect2
- IQCN | c.1761T>C p.H587= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV66575670; called by muse, mutect2, varscan2
- KCNT2 | c.3081A>G p.K1027= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV54093084; called by muse, mutect2, varscan2
- MAMDC4 | c.231C>T p.D77= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs767345735, COSV56034058; called by muse, mutect2, varscan2
- NKAPL | c.399G>A p.A133= | Silent (SNP) | VAF 49/257 reads (19%) | catalogued as COSV59196834; called by muse, mutect2, varscan2
- NR0B1 | c.816G>A p.L272= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV66764388; called by muse, mutect2, varscan2
- OLFM3 | c.471C>T p.I157= (on ENST00000338858 / NM_001288821.1; = p.I137= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV58801152; called by muse, mutect2, varscan2
- OR10Z1 | c.249T>C p.S83= | Silent (SNP) | VAF 65/393 reads (17%) | catalogued as COSV63525663; called by muse, mutect2, varscan2
- OR2AK2 | c.540A>G p.E180= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV63547689, COSV63557042; called by muse, varscan2
- OR2M2 | c.546T>G p.P182= | Silent (SNP) | VAF 80/442 reads (18%) | catalogued as COSV62898893; called by muse, mutect2, varscan2
- OR4C6 | c.363C>T p.Y121= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs141756140; called by muse, mutect2, varscan2
- OR8K1 | c.30G>C p.T10= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV54401752, COSV54403538; called by muse, mutect2, varscan2
- PAX1 | c.612C>T p.G204= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs779633330; called by muse, mutect2, varscan2
- PCDH18 | c.2067T>C p.T689= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV61270205; called by muse, mutect2
- PCDHB12 | c.1845C>T p.F615= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs782157614, COSV99507857; called by muse, mutect2, varscan2
- PLA2G2C | c.381C>T p.P127= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1390251185, COSV56124729, COSV99930191; called by muse, mutect2, varscan2
- PTPRD | c.2112T>C p.I704= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV61963381; called by muse, mutect2
- RECQL | c.1293G>T p.V431= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV53710688; called by muse, mutect2, varscan2
- RPIA | c.843G>T p.V281= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs766575101, COSV52170665; called by muse, mutect2, varscan2
- SCN11A | c.2058T>G p.T686= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV56573923; called by muse, mutect2, varscan2
- SCN5A | c.5067C>T p.D1689= (on ENST00000333535 / NM_198056.3; = p.D1688= on NM_000335.5) | Silent (SNP) | VAF 32/240 reads (13%) | catalogued as rs557836660, COSV61115776; called by muse, mutect2, varscan2
- SH2D4A | c.657G>A p.T219= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs747333013, COSV56121909, COSV56124711; called by muse, mutect2, varscan2
- SKIL | c.252C>T p.P84= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV52061111; called by muse, mutect2, varscan2
- SPEF2 | c.2427C>T p.H809= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as rs374907687; called by muse, mutect2, varscan2
- ST8SIA4 | c.537A>T p.A179= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- TPH2 | c.81G>A p.E27= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1468665210, COSV61592982; called by muse, mutect2, varscan2
- UBQLNL | c.708A>G p.Q236= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs780245057, COSV66493403, COSV66494024; called by muse, mutect2, varscan2
- UQCRFS1 | c.804C>T p.D268= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1335699539, COSV59185158; called by muse, mutect2
- WDR6 | c.3045G>A p.E1015= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as COSV58246159; called by muse, varscan2
- ZDBF2 | c.5022T>C p.H1674= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- ZNF398 | c.1234A>C p.R412= (on ENST00000475153 / NM_170686.3; = p.R241= on NM_020781.4) | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV60066001; called by muse, mutect2, varscan2
- ZNF518B | c.2349C>T p.S783= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV58723546; called by muse, mutect2, varscan2
- ZNF676 | c.651T>G p.T217= (on ENST00000650058; = p.T185= on NM_001001411.3) | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV101236291; called by muse, mutect2, varscan2
- C1orf43 | c.*1C>T | 3'UTR (SNP) | VAF 28/199 reads (14%) | catalogued as rs761481558, COSV100634169; called by muse, mutect2, varscan2
- DHRS4L1 | n.50T>G | RNA (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5196C>T | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as rs142630054; called by muse, mutect2, varscan2
- MIR125B2 | n.33T>G | RNA (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- MIR519A1 | n.29G>A | RNA (SNP) | VAF 16/155 reads (10%) | catalogued as rs191444009; called by muse, mutect2, varscan2
